Surgical pathology report (de-identified scan), TCGA case TCGA-BR-A4PF, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-A4PF-01A (Primary Tumor).

Gross Description:

Microscopic Description:

Diagnosis Details:

Comments:

Formatted Path Reports: STOMACH TISSUE CHECKLIST

Specimen type: Excision of tumor

Tumor site: Antrum

Tumor size: 10 x 7 x 1.5 cm

Tumor features: Ulcerated

Histologic type: Adenocarcinoma

Histologic grade: Poorly differentiated

Tumor extent: Serosa (visceral peritoneum)

Lymph nodes: 3/8 positive for metastasis (Intraabdominal 3/8)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Perineural invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Tumor penetrates through all layers of stomach and invades serosa (visceral peritoneum).

Comments: None

ICD-0.3
adenocarcinoma, NOS 8140/3
site: stomach, antrum C16.3
hw
10/5/12

Reviewed by (initials)	hw 10/5/12	

Source: NCI Genomic Data Commons file 98fd3284-60cd-4e41-ab7c-71a5243b60e1 (TCGA-BR-A4PF.8C379B7F-4EAB-4AAA-A90E-8088BEE63AAE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).